Somatic mutation profile of tumor specimen TCGA-55-1595-01A (aliquot TCGA-55-1595-01A-01D-0969-08) from TCGA case TCGA-55-1595, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-55-1595-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dfa07b9-3d69-4974-9a29-336b47b0cdab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-1595-11A (Solid Tissue Normal), aliquot TCGA-55-1595-11A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a48e132-74fa-456d-a292-a958d9373e3d

The open-access MAF lists 341 somatic variants for this specimen: 252 protein-altering or splice-affecting, 81 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 217, Silent 81, Nonsense Mutation 21, Splice Site 8, Intron 5, Frame Shift Del 4, Frame Shift Ins 2, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/24 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA13 | c.3089G>C p.C1030S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70027070; called by muse, mutect2
- ABCA9 | c.2768-2A>G p.X923_splice | Splice Site (SNP) | VAF 59/378 reads (16%) | catalogued as COSV60622544; called by muse, mutect2, varscan2
- ABCC10 | c.3031G>T p.A1011S (on ENST00000372530 / NM_001198934.2; = p.A983S on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55085995; called by muse, mutect2
- AC100868.1 | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 18/148 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99227180; called by muse, varscan2
- ACKR1 | c.823A>T p.T275S | Missense Mutation (SNP) | VAF 71/555 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.228); catalogued as COSV63672287; called by muse, mutect2, varscan2
- ACOX1 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV53132180; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4007G>C p.G1336A | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV65877440, COSV65878482; called by muse, mutect2, varscan2
- ADCY6 | c.1226C>T p.A409V | Missense Mutation (SNP) | VAF 58/107 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV57169643, COSV57170632; called by muse, mutect2, varscan2
- ADCY6 | c.1225G>T p.A409S | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100327001; called by muse, mutect2, varscan2
- AKR1B10 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV62055208; called by muse, mutect2, varscan2
- ANKFN1 | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs376046142; called by mutect2, varscan2
- AQP2 | c.319A>C p.I107L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs529388515, COSV52229684; called by muse, varscan2
- ASTN1 | c.386C>A p.P129Q | Missense Mutation (SNP) | VAF 41/312 reads (13%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.013); catalogued as COSV56065194; called by muse, mutect2, varscan2
- ATM | c.883G>C p.A295P | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53735052; called by muse, mutect2, varscan2
- ATM | c.6128G>T p.G2043V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs753384717, COSV53735072; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP11C | c.2189T>A p.L730Q | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.786); catalogued as COSV59561166; called by muse, mutect2, varscan2
- BCL9 | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 141/240 reads (59%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.849); catalogued as COSV52342481; called by muse, mutect2, varscan2
- BTAF1 | c.4437T>A p.S1479R | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs754346364, COSV56431571; called by muse, mutect2, varscan2
- BTBD6 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as rs775976434, COSV100527898; called by muse, mutect2, varscan2
- C4BPA | c.520A>T p.K174* | Nonsense Mutation (SNP) | VAF 25/172 reads (15%) | catalogued as COSV65536072; called by muse, mutect2, varscan2
- C6orf58 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV61666272; called by muse, mutect2, varscan2
- C8B | c.1245G>T p.K415N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV64777151; called by muse, mutect2, varscan2
- C9orf131 | c.2688C>A p.S896R | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV56610205, COSV56610678; called by muse, mutect2, varscan2
- CABS1 | c.162T>A p.Y54* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV56733271; called by muse, mutect2, varscan2
- CASZ1 | c.4099G>C p.E1367Q | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59734006; called by muse, mutect2, varscan2
- CCDC178 | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 66/76 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55766494; called by muse, mutect2, varscan2
- CCDC73 | c.2674G>T p.D892Y | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58796957; called by muse, mutect2, varscan2
- CCDC87 | c.1783G>T p.D595Y | Missense Mutation (SNP) | VAF 204/250 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV59578680; called by muse, mutect2, varscan2
- CDH8 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54857457; called by muse, mutect2, varscan2
- CDYL2 | c.1219-2A>T p.X407_splice | Splice Site (SNP) | VAF 4/10 reads (40%) | catalogued as rs865822442, COSV73653948; called by muse, mutect2, varscan2
- CEP41 | c.281A>C p.N94T | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV56219053; called by muse, mutect2, varscan2
- CFAP47 | c.4866A>T p.K1622N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.925); catalogued as COSV57972461; called by muse, mutect2, varscan2
- CHD8 | c.4690G>T p.E1564* (on ENST00000646647 / NM_001170629.2; = p.E1285* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as rs1356662563, COSV63218920, COSV63219091; called by muse, mutect2, varscan2
- CIART | c.19G>T p.V7F | Missense Mutation (SNP) | VAF 36/307 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.442); catalogued as COSV51743629; called by muse, mutect2, varscan2
- CLCA4 | c.1298T>A p.V433D | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55367273; called by muse, mutect2, varscan2
- CNBD1 | c.608T>A p.L203Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV72976014; called by muse, mutect2, varscan2
- CNGB3 | c.450G>T p.L150F | Missense Mutation (SNP) | VAF 28/348 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201881873, COSV60687200; ClinVar: likely benign; called by muse, mutect2
- CNTNAP2 | c.1673G>T p.C558F | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62160683; called by muse, mutect2, varscan2
- COL11A1 | c.367G>A p.G123S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs1309002302, COSV62177699; called by muse, mutect2
- COL15A1 | c.2707G>A p.G903R | Missense Mutation (SNP) | VAF 31/309 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66642842; called by muse, mutect2, varscan2
- COL22A1 | c.3863G>T p.G1288V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57330148; called by muse, mutect2
- COL25A1 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV67648246; called by muse, mutect2, varscan2
- COL5A3 | c.437+1G>A p.X146_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV53408367; called by mutect2, varscan2
- COMMD8 | c.485G>A p.R162K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67500327; called by muse, mutect2, varscan2
- CORO1A | c.521T>C p.V174A | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV54630795; called by muse, mutect2, varscan2
- CRISP1 | c.473T>C p.I158T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV59993146; called by muse, mutect2, varscan2
- CSMD1 | c.2701G>A p.D901N (on ENST00000520002; = p.D900N on NM_033225.6) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV59301702; called by muse, mutect2, varscan2
- CSMD3 | c.10714G>T p.E3572* (on ENST00000297405 / NM_001363185.1; = p.E3403* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 52/118 reads (44%) | catalogued as COSV52139070, COSV52186456; called by muse, mutect2, varscan2
- CTAGE1 | c.565C>A p.Q189K | Missense Mutation (SNP) | VAF 266/333 reads (80%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.702); catalogued as COSV66943180; called by muse, mutect2, varscan2
- CTNNA2 | c.1514C>A p.S505* | Nonsense Mutation (SNP) | VAF 8/48 reads (17%) | catalogued as COSV58143442, COSV58154065; called by muse, mutect2, varscan2
- CYLC2 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.934); catalogued as COSV66336854, COSV66338490; called by muse, mutect2, varscan2
- CYP2E1 | c.1156-1G>T p.X386_splice | Splice Site (SNP) | VAF 8/54 reads (15%) | catalogued as COSV53312844; called by mutect2, varscan2
- CYP4F8 | c.1544G>T p.R515L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.214); catalogued as rs1317466521, COSV57853591; called by muse, mutect2, varscan2
- CYP4X1 | c.44A>T p.Y15F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.342); catalogued as COSV64150110; called by muse, mutect2, varscan2
- CYP7B1 | c.123G>T p.R41S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV59585243, COSV59586168; called by muse, mutect2
- DCAF12L1 | c.703A>T p.S235C | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV64421428; called by muse, mutect2, varscan2
- DCD | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.461); catalogued as COSV53201332; called by muse, mutect2, varscan2
- DMBT1 | c.5081G>T p.G1694V (on ENST00000338354 / NM_001377530.1; = p.G937V on NM_004406.3) | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377104506, COSV57567625; called by muse, mutect2, varscan2
- DMD | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 26/92 reads (28%) | catalogued as CD165354, CM118632, COSV63743812; called by muse, mutect2, varscan2
- DMD | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as COSV55861718, COSV55871792; called by muse, mutect2, varscan2
- DNAH7 | c.6531G>T p.L2177F | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV56757659; called by muse, mutect2, varscan2
- DSE | c.2749G>T p.A917S | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.418); catalogued as COSV59062742; called by muse, mutect2, varscan2
- DUOX2 | c.2842G>T p.G948C | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.395); catalogued as COSV66531310; called by muse, mutect2, varscan2
- EDC4 | c.4195A>T p.S1399C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.339); catalogued as COSV59302301; called by muse, mutect2, varscan2
- EDN2 | c.260G>T p.R87L | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs757449064, COSV101006366, COSV65423714; called by muse, mutect2, varscan2
- EDN3 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.72); catalogued as COSV61107277; called by muse, mutect2, varscan2
- EGLN2 | c.1169-2A>C p.X390_splice | Splice Site (SNP) | VAF 13/38 reads (34%) | catalogued as COSV100393879; called by muse, mutect2, varscan2
- ENPP1 | c.2611G>T p.G871W | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62931254; called by muse, mutect2, varscan2
- EOLA2 | c.287C>A p.P96H | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62207097; called by muse, mutect2, varscan2
- EPC2 | c.2105A>T p.H702L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.73); PolyPhen benign (0.187); catalogued as COSV51542007; called by muse, mutect2, varscan2
- EPHA6 | c.1851C>A p.Y617* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as COSV67565763; called by muse, mutect2, varscan2
- FAM214A | c.694A>G p.N232D | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV55923120; called by muse, mutect2, varscan2
- FAM3A | c.341G>T p.S114I | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as COSV100453720; called by muse, mutect2, varscan2
- FAM71B | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV57228214; called by muse, mutect2, varscan2
- FAT2 | c.11453T>A p.V3818D | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV55816390; called by muse, mutect2, varscan2
- FAT4 | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV67883342, COSV67901225; called by muse, mutect2, varscan2
- FERMT2 | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58406032; called by muse, mutect2, varscan2
- FLT4 | c.1317C>A p.S439R | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV56103046; called by muse, mutect2, varscan2
- FMN2 | c.3349G>T p.G1117C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV60424821; called by muse, varscan2
- FOCAD | c.67C>T p.H23Y | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.2); PolyPhen benign (0.405); catalogued as rs763980249, COSV58096214; called by muse, mutect2, varscan2
- FTSJ1 | c.875C>A p.P292H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.319); catalogued as COSV50025629; called by muse, mutect2, varscan2
- GALNT14 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 99/182 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61103741; called by muse, mutect2, varscan2
- GATB | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 28/85 reads (33%) | catalogued as COSV56129584; called by muse, mutect2, varscan2
- GBP7 | c.1653C>A p.H551Q | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.223); catalogued as COSV54008966; called by muse, varscan2
- GCN1 | c.2923G>T p.A975S | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.866); catalogued as COSV56105601; called by muse, mutect2, varscan2
- GLRA2 | c.1096C>A p.R366S | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.118); catalogued as COSV54335383, COSV54338436; called by muse, mutect2, varscan2
- GPR139 | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750115024, COSV100430045, COSV58502171; called by muse, mutect2, varscan2
- GPR142 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 47/182 reads (26%) | catalogued as COSV59519001; called by muse, mutect2, varscan2
- GPR85 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51783074; called by muse, mutect2, varscan2
- GRIA1 | c.2318T>C p.L773S | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53589615, COSV99602834; called by muse, mutect2, varscan2
- GRIK1 | c.390C>A p.H130Q | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV58714139; called by muse, mutect2, varscan2
- GRIK4 | c.1192C>A p.L398I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as COSV70801128; called by muse, mutect2, varscan2
- GUCY2F | c.1849G>T p.G617W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54300107; called by muse, mutect2, varscan2
- HHIPL2 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 118/206 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs182677675, COSV58564163, COSV58567430; called by muse, mutect2, varscan2
- HK3 | c.2599G>T p.D867Y | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759322336, COSV52838243, COSV52841287; called by muse, mutect2, varscan2
- HNRNPCL1 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV58610662; called by muse, mutect2, varscan2
- HSD3B2 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65592895; called by muse, mutect2, varscan2
- HSPB1 | c.574G>T p.G192W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs765430725, COSV99949277; ClinVar: uncertain significance; called by mutect2, varscan2
- HTR1F | c.305T>A p.V102D | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60389346; called by muse, mutect2, varscan2
- HUS1 | c.656A>T p.H219L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1198579054, COSV51839129; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1971C>G p.N657K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61148975; called by muse, mutect2
- ING1 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs200198352, COSV58168110; called by muse, varscan2
- INTS13 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.768); catalogued as COSV53901802; called by muse, mutect2, varscan2
- ISL1 | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs768556500, COSV57932956; called by muse, mutect2, varscan2
- ITGAX | c.1314G>C p.Q438H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs1252901202, COSV51643939; called by muse, mutect2, varscan2
- ITPR2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV67266998; called by muse, mutect2
- ITPRID1 | c.968A>G p.D323G | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV60072112; called by muse, mutect2, varscan2
- KANK4 | c.668G>T p.R223L | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs767511820, COSV62986019, COSV62987854; called by muse, mutect2, varscan2
- KASH5 | c.1453del p.E485Nfs*9 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | catalogued as COSV101483432; called by mutect2, pindel, varscan2
- KCNK2 | c.733T>C p.F245L (on ENST00000444842 / NM_001017425.3; = p.F230L on NM_014217.4) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs978654379, COSV67204417; called by muse, mutect2, varscan2
- KCNV1 | c.1495T>C p.W499R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52085373; called by muse, mutect2, varscan2
- KCNV2 | c.1180T>G p.S394A | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66055743; called by muse, mutect2, varscan2
- KDM3B | c.3158G>T p.C1053F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100070304, COSV58689448; called by muse, mutect2, varscan2
- KIAA1109 | c.6623C>T p.T2208I | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.991); catalogued as rs899971626, COSV52666968; called by muse, mutect2, varscan2
- KIAA1549 | c.5080G>T p.A1694S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54309503, COSV99651585; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- KLHDC4 | c.1324G>A p.G442R | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs984831599, COSV54506894; called by muse, mutect2, varscan2
- KLK5 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60449889; called by muse, mutect2, varscan2
- KLRF1 | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as rs1408683246, COSV54380583; called by muse, mutect2, varscan2
- L1TD1 | c.2429T>A p.V810D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV63133330; called by muse, mutect2, varscan2
- LBP | c.590T>A p.I197N | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54139465; called by muse, mutect2, varscan2
- LILRB1 | c.1112C>A p.T371K (on ENST00000427581; = p.T335K on NM_006669.6) | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV61116922; called by muse, mutect2, varscan2
- LILRB3 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs760730319; called by muse, mutect2, varscan2
- LRRN1 | c.1811A>G p.Q604R | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.034); catalogued as COSV60013146; called by muse, mutect2, varscan2
- LTBP1 | c.4711G>A p.D1571N (on ENST00000404816 / NM_206943.4; = p.D1245N on NM_000627.4) | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.697); catalogued as COSV55377527, COSV99698023; called by muse, mutect2, varscan2
- LTBP2 | c.1903G>C p.A635P | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100000313, COSV56206352; called by muse, mutect2, varscan2
- LYAR | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as COSV100603503, COSV58642452; called by muse, mutect2, varscan2
- MAFG | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs772676495, COSV100155797; called by muse, mutect2, varscan2
- MAOB | c.911C>G p.P304R | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.911); catalogued as COSV65204706; called by muse, mutect2, varscan2
- MARCHF11 | c.587A>T p.H196L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60127307; called by muse, mutect2, varscan2
- MARS2 | c.1645G>T p.G549* | Nonsense Mutation (SNP) | VAF 77/263 reads (29%) | catalogued as COSV56570979; called by muse, mutect2, varscan2
- MBD4 | c.752G>T p.R251M | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs1343817231, COSV51444255; called by muse, mutect2, varscan2
- MBL2 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.186); catalogued as COSV64758154; called by muse, mutect2, varscan2
- MGAT5B | c.1840A>G p.R614G (on ENST00000569840 / NM_001199172.2; = p.R612G on NM_144677.3) | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56927389; called by muse, mutect2, varscan2
- MKRN3 | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs532500484, COSV58808687, COSV58809315; called by muse, mutect2, varscan2
- MME | c.1726G>T p.G576W | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64706579; called by muse, mutect2, varscan2
- MMP16 | c.1676C>A p.A559D | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.296); catalogued as COSV54157432; called by muse, mutect2, varscan2
- MOK | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51964313; called by muse, mutect2, varscan2
- MORC1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | catalogued as COSV51716931; called by muse, mutect2, varscan2
- MORC1 | c.143A>T p.D48V | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1377748177, COSV51716948; called by muse, mutect2, varscan2
- MSH4 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 8/57 reads (14%) | catalogued as COSV54199706; called by muse, mutect2, varscan2
- MTM1 | c.1600T>C p.W534R | Missense Mutation (SNP) | VAF 64/122 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM133041, COSV60334297; called by muse, mutect2, varscan2
- MUC17 | c.266C>A p.P89H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); catalogued as COSV60284005; called by muse, mutect2, varscan2
- MYO16 | c.1382C>A p.S461Y | Missense Mutation (SNP) | VAF 95/181 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV51784348; called by muse, mutect2, varscan2
- NCAM2 | c.1637G>T p.R546L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV53064796; called by muse, mutect2, varscan2
- NFATC2 | c.1987G>T p.G663W | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354264; called by muse, mutect2, varscan2
- NLGN1 | c.107G>C p.C36S | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV64327761; called by muse, mutect2, varscan2
- NLGN1 | c.1638T>A p.F546L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV64327769; called by muse, mutect2, varscan2
- NLRP4 | c.1578G>T p.E526D | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); catalogued as COSV56711128, COSV56714631, COSV56721582; called by muse, mutect2, varscan2
- NLRP5 | c.2423C>A p.P808H | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV66763257; called by muse, mutect2, varscan2
- NLRX1 | c.1104C>G p.C368W | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52702748; called by muse, mutect2, varscan2
- NSUN2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV52953344; called by muse, mutect2, varscan2
- NTRK3 | c.1811A>T p.Y604F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.38); catalogued as COSV62294493, COSV62299577; called by muse, mutect2, varscan2
- OCRL | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV63980576; called by muse, mutect2, varscan2
- OR10A7 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs747699855, COSV100406643, COSV58277910, COSV58278612; called by muse, mutect2, varscan2
- OR14C36 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.107); catalogued as COSV100507347, COSV58600821; called by muse, mutect2
- OR14I1 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs767063023, COSV61199263, COSV61199290; called by muse, mutect2, varscan2
- OR2J2 | c.751C>A p.L251I | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.248); catalogued as COSV65847852; called by muse, mutect2, varscan2
- OR2L2 | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 75/369 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV63550503, COSV63550599; called by muse, mutect2, varscan2
- OR4C16 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV58941329; called by muse, mutect2, varscan2
- OR4E2 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 29/173 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100330174; called by muse, mutect2, varscan2
- OR51A2 | c.93C>G p.I31M | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV100985108; called by muse, mutect2, varscan2
- OR5AC2 | c.158A>T p.N53I | Missense Mutation (SNP) | VAF 167/293 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100684532; called by muse, mutect2, varscan2
- OSBPL7 | c.1423G>T p.A475S | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50107646; called by muse, mutect2, varscan2
- OTUD7B | c.2111del p.G704Afs*124 | Frame Shift Del (DEL) | VAF 19/140 reads (14%) | catalogued as COSV64918134; called by mutect2, pindel, varscan2
- PAPPA2 | c.3927C>G p.H1309Q | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV62793947; called by muse, mutect2, varscan2
- PARD3 | c.3812G>T p.G1271V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61052103; called by muse, mutect2, varscan2
- PARD3B | c.1724C>G p.S575C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62506728; called by muse, mutect2, varscan2
- PCDH15 | c.983T>A p.V328D | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV57282934; called by muse, mutect2, varscan2
- PCDH18 | c.2794T>A p.W932R | Missense Mutation (SNP) | VAF 51/253 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61267285; called by muse, mutect2, varscan2
- PCDHB10 | c.2104C>A p.L702I | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53377095; called by muse, varscan2
- PCLO | c.3991C>G p.Q1331E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV61624681; called by muse, mutect2, varscan2
- PCSK6 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59339535; called by muse, mutect2, varscan2
- PI15 | c.274-1G>T p.X92_splice | Splice Site (SNP) | VAF 72/161 reads (45%) | catalogued as COSV52640402, COSV52643932; called by muse, varscan2
- PIK3C2G | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.116); catalogued as COSV56803322; called by muse, mutect2, varscan2
- PIK3R5 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV52651950; called by muse, mutect2, varscan2
- PIWIL1 | c.1160G>T p.C387F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55345283; called by muse, mutect2, varscan2
- PKP3 | c.2061G>T p.R687S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV100229699, COSV58986560; called by muse, mutect2, varscan2
- PLAGL2 | c.511C>A p.L171M | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55787903; called by muse, mutect2, varscan2
- PLIN2 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 70/249 reads (28%) | catalogued as COSV99439249; called by muse, mutect2, varscan2
- PRB2 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 351/942 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.253); catalogued as COSV66982664, COSV66982684; called by muse, varscan2
- PROM2 | c.505G>T p.V169L | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as COSV58297459; called by muse, mutect2, varscan2
- PRRC2C | c.6434G>T p.S2145I (on ENST00000367742; = p.S2143I on NM_015172.4) | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV58903054; called by muse, mutect2, varscan2
- PTER | c.422C>G p.S141* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV54345146; called by muse, mutect2, varscan2
- PTPN3 | c.2440G>C p.V814L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.181); catalogued as COSV52704335; called by muse, mutect2, varscan2
- PTPRD | c.2350-2A>G p.X784_splice | Splice Site (SNP) | VAF 27/131 reads (21%) | catalogued as COSV61936014; called by muse, mutect2, varscan2
- PXDNL | c.3889G>C p.D1297H | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1318009055, COSV62483649; called by muse, mutect2, varscan2
- R3HDM2 | c.2596G>T p.G866W | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV60413889; called by muse, mutect2
- RAD51AP2 | c.2800G>T p.G934C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs752212419, COSV67587637; called by mutect2, varscan2
- RAD51AP2 | c.2578G>T p.E860* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV67587641; called by muse, mutect2, varscan2
- RASAL2 | c.159G>T p.R53S | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV62711751, COSV62716546; called by muse, mutect2, varscan2
- REG3A | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as rs1048512257, COSV59408975, COSV59410712, COSV59411752; called by muse, mutect2, varscan2
- REPS2 | c.1654G>C p.A552P | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.189); catalogued as COSV58180481; called by muse, mutect2, varscan2
- RGL1 | c.41A>T p.D14V (on ENST00000360851 / NM_001297672.2; = p.D49V on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58982119; called by muse, mutect2
- RNF14 | c.1023dup p.L342Vfs*10 | Frame Shift Ins (INS) | VAF 30/167 reads (18%) | catalogued as rs1405159200; called by mutect2, pindel, varscan2
- RNF144B | c.158G>C p.C53S | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52569081; called by muse, mutect2, varscan2
- RPH3A | c.1891G>A p.A631T (on ENST00000389385 / NM_001143854.2; = p.A627T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.56); catalogued as COSV66990428; called by muse, mutect2, varscan2
- RTL4 | c.884C>A p.A295D | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV61205896; called by muse, mutect2
- RYR1 | c.8531A>T p.Q2844L | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV62093324; called by muse, mutect2, varscan2
- SDK1 | c.3578G>T p.R1193L | Missense Mutation (SNP) | VAF 54/246 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs376638701, COSV67361980, COSV67362501; called by muse, mutect2, varscan2
- SDK2 | c.5606G>T p.W1869L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66183727; called by muse, mutect2
- SEC14L5 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760561073, COSV52037295; called by muse, mutect2, varscan2
- SEMA6B | c.1009T>A p.C337S | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56703026, COSV56705302; called by muse, mutect2, varscan2
- SEPTIN6 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV59713198; called by muse, mutect2, varscan2
- SHANK3 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV99438193; called by muse, mutect2, varscan2
- SHANK3 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99438199; called by muse, mutect2, varscan2
- SIPA1L3 | c.1640A>G p.Y547C | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55911305; called by muse, mutect2, varscan2
- SLC10A3 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 97/274 reads (35%) | catalogued as COSV54835950; called by muse, mutect2, varscan2
- SNAPC4 | c.2279C>T p.T760I | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53731966; called by muse, mutect2, varscan2
- SNX32 | c.700G>C p.A234P | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57448909, COSV57449166; called by muse, mutect2, varscan2
- SNX33 | c.767C>G p.P256R | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100145910; called by muse, mutect2, varscan2
- SOWAHB | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 20/76 reads (26%) | catalogued as COSV57554218; called by muse, mutect2, varscan2
- SPATA31E1 | c.487G>C p.G163R | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57790476; called by muse, mutect2, varscan2
- SPATA9 | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV57223548; called by muse, mutect2, varscan2
- SPTA1 | c.3799C>A p.L1267M | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63750953; called by muse, mutect2, varscan2
- SSTR2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs781058496, COSV59535048; called by muse, mutect2
- ST8SIA6 | c.1030T>A p.W344R | Missense Mutation (SNP) | VAF 48/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66467028; called by muse, mutect2, varscan2
- STAM | c.708T>G p.I236M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV66325098; called by muse, varscan2
- STAT5B | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV53181404; called by muse, mutect2, varscan2
- SYN3 | c.568C>G p.P190A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV60504855; called by muse, mutect2, varscan2
- TACR3 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.024); catalogued as rs201442145, COSV100510428, COSV59199712; called by muse, mutect2, varscan2
- TAS2R16 | c.121A>T p.R41W | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV50796950; called by muse, mutect2, varscan2
- TASOR | c.2435A>T p.H812L (on ENST00000355628 / NM_001365636.2; = p.H416L on NM_015224.3) | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV100843722; called by muse, mutect2, varscan2
- TEC | c.1202G>T p.R401L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1484539226, COSV67404183; called by muse, mutect2, varscan2
- TIAM1 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.09); catalogued as COSV54543669; called by muse, mutect2, varscan2
- TMC1 | c.2273G>T p.G758V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV52771879; called by muse, mutect2, varscan2
- TOX4 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99398708; called by muse, mutect2, varscan2
- TRIP12 | c.65G>C p.G22A | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.007); catalogued as COSV52261289, COSV52264451; called by muse, mutect2, varscan2
- TTN | c.81050C>G p.P27017R (on ENST00000591111; = p.P19593R on NM_003319.4) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | PolyPhen probably damaging (0.919); catalogued as COSV59961526, COSV60027655; called by muse, mutect2, varscan2
- TTN | c.10548G>T p.M3516I (on ENST00000591111; = p.M3470I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as COSV59961553; called by muse, varscan2
- UGT2A1 | c.1404C>A p.H468Q | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54139682; called by muse, mutect2, varscan2
- UNC13C | c.2298G>T p.L766F | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs778064943, COSV52855901; called by muse, mutect2, varscan2
- USH2A | c.11044G>A p.E3682K | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV56348201, COSV56358604; called by muse, mutect2, varscan2
- USH2A | c.2396C>G p.T799R | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV56348279; called by muse, mutect2, varscan2
- VANGL2 | c.862C>T p.P288S | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs751396709, COSV63604243; called by muse, mutect2, varscan2
- YIPF7 | c.38T>C p.L13S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV60656394; called by muse, mutect2, varscan2
- ZCWPW2 | c.208A>T p.N70Y | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV67498182; called by muse, mutect2, varscan2
- ZNF285 | c.851G>C p.G284A | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.112); catalogued as COSV58408440, COSV58409366; called by muse, mutect2, varscan2
- ZNF365 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101238006; called by muse, mutect2, varscan2
- ZNF496 | c.898C>G p.P300A | Missense Mutation (SNP) | VAF 48/202 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV54175367; called by mutect2, varscan2
- ZNF676 | c.1500G>T p.K500N (on ENST00000650058; = p.K468N on NM_001001411.3) | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV68092631, COSV68093546, COSV68095054; called by muse, mutect2, varscan2
- ABL2 | c.392-4_427del p.X131_splice (on ENST00000502732 / NM_007314.4; = p.X116_splice on NM_005158.5) | Splice Site (DEL) | VAF 10/82 reads (12%) | called by mutect2, pindel
- COL24A1 | c.1425dup p.E476* | Frame Shift Ins (INS) | VAF 9/52 reads (17%) | called by mutect2, pindel, varscan2
- FRG2 | c.698A>T p.Y233F | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.953); called by muse, mutect2
- IGKV1D-8 | c.194C>A p.A65D | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, varscan2
- MUC16 | c.19669del p.A6557Hfs*36 | Frame Shift Del (DEL) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
- PITRM1 | c.1017C>A p.D339E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.681); called by muse, mutect2
- SP2 | c.1118del p.P373Qfs*22 | Frame Shift Del (DEL) | VAF 20/196 reads (10%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.2974C>A p.P992T | Missense Mutation (SNP) | VAF 61/308 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRAV7 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TRBV3-1 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCC6 | c.1461G>T p.R487= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV52742424; called by muse, mutect2, varscan2
- ADAM11 | c.1833G>T p.R611= | Silent (SNP) | VAF 111/236 reads (47%) | catalogued as COSV52345289; called by muse, mutect2, varscan2
- ADAMTS16 | c.2853C>A p.P951= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as COSV56983588, COSV57009648; called by muse, mutect2, varscan2
- ADGRG4 | c.699T>C p.N233= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV54952493; called by muse, mutect2, varscan2
- ADGRG4 | c.2454A>C p.V818= | Silent (SNP) | VAF 76/169 reads (45%) | catalogued as COSV54952500; called by muse, mutect2, varscan2
- ALB | c.729G>C p.L243= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as COSV55736846; called by muse, mutect2, varscan2
- CACNA1H | c.4119G>T p.L1373= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV61986771; called by muse, varscan2
- CARD11 | c.2010G>C p.T670= | Silent (SNP) | VAF 18/146 reads (12%) | catalogued as COSV62754682, COSV62755373; called by muse, mutect2, varscan2
- CCDC89 | c.804C>T p.V268= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV57033727; called by muse, mutect2, varscan2
- CHAT | c.1294C>A p.R432= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV60320857; called by muse, mutect2, varscan2
- CLDN14 | c.360C>A p.L120= | Silent (SNP) | VAF 33/159 reads (21%) | catalogued as COSV59772605, COSV59777878; called by muse, mutect2, varscan2
- CNGA2 | c.1491C>A p.G497= | Silent (SNP) | VAF 12/192 reads (6%) | catalogued as rs968385858, COSV61703816; called by muse, mutect2
- CNTNAP4 | c.864G>A p.V288= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV56672406; called by muse, mutect2, varscan2
- CRX | c.381C>A p.P127= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs749025279, COSV55757552; called by muse, mutect2, varscan2
- DCLK2 | c.747T>C p.D249= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs922380783, COSV56201693; called by muse, mutect2, varscan2
- DGKI | c.2406C>G p.G802= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV55943136; called by muse, mutect2, varscan2
- DNPEP | c.1398C>T p.T466= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1317602503, COSV56110487; called by muse, mutect2
- EPB41L4B | c.627A>G p.L209= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as rs753599575, COSV65796342; called by muse, mutect2, varscan2
- EPHA5 | c.1182A>T p.A394= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV56637671; called by muse, mutect2, varscan2
- EREG | c.201G>A p.K67= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV55261022; called by muse, mutect2, varscan2
- FGD5 | c.1287C>T p.P429= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1243964806, COSV53239841; called by muse, mutect2, varscan2
- GALNT9 | c.1503G>T p.V501= (on ENST00000328957 / NM_001122636.2; = p.V135= on NM_021808.3) | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV61097236; called by muse, mutect2, varscan2
- GEMIN4 | c.1944A>G p.P648= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV56745398; called by muse, mutect2, varscan2
- H2BC9 | c.21C>T p.S7= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as COSV55099608; called by muse, mutect2
- HCN1 | c.1833T>C p.T611= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs1390026366, COSV57501230; called by muse, mutect2, varscan2
- HS3ST3B1 | c.738C>T p.P246= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs746406312, COSV100714426; called by muse, mutect2, varscan2
- HSFX1 | c.13C>A p.R5= | Silent (SNP) | VAF 74/287 reads (26%) | called by muse, mutect2, varscan2
- IDH3G | c.909C>T p.Y303= | Silent (SNP) | VAF 117/271 reads (43%) | catalogued as rs782310754, COSV54206792; called by muse, mutect2, varscan2
- IGHV1-45 | c.210C>A p.I70= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, varscan2
- IGHV1OR21-1 | c.282C>T p.S94= | Silent (SNP) | VAF 37/464 reads (8%) | catalogued as rs769043817; called by muse, mutect2
- IL9R | c.549G>A p.L183= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV54898844; called by muse, mutect2
- ITGAD | c.2445G>T p.V815= | Silent (SNP) | VAF 54/182 reads (30%) | catalogued as COSV66757336; called by mutect2, varscan2
- ITIH5 | c.30G>T p.G10= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99906113; called by muse, mutect2, varscan2
- KLF3 | c.417G>T p.P139= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV54710141; called by muse, mutect2, varscan2
- MEP1A | c.1464G>A p.V488= | Silent (SNP) | VAF 31/299 reads (10%) | catalogued as COSV57919104; called by muse, mutect2, varscan2
- MYCT1 | c.448C>T p.L150= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs1298313770, COSV65891140; called by muse, mutect2, varscan2
- MYH1 | c.1281G>T p.V427= | Silent (SNP) | VAF 50/264 reads (19%) | catalogued as COSV56845841, COSV56859170; called by muse, mutect2, varscan2
- MYO5C | c.1926G>T p.T642= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV55904424; called by muse, mutect2, varscan2
- NDST1 | c.1668C>G p.L556= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as COSV55785830; called by muse, mutect2, varscan2
- NDST4 | c.180T>C p.Y60= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as rs757909216, COSV52113595; called by muse, mutect2, varscan2
- OR2L13 | c.117G>C p.V39= | Silent (SNP) | VAF 31/241 reads (13%) | catalogued as COSV63550506; called by muse, mutect2, varscan2
- OR4E2 | c.474G>T p.G158= | Silent (SNP) | VAF 28/171 reads (16%) | catalogued as rs988958426, COSV100330175; called by muse, mutect2, varscan2
- OR5A1 | c.408C>A p.P136= | Silent (SNP) | VAF 117/278 reads (42%) | catalogued as rs768387584, COSV100118495; called by muse, varscan2
- OXCT1 | c.1509G>C p.G503= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV52168962; called by muse, mutect2, varscan2
- P2RY8 | c.837G>T p.L279= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV67176999; called by muse, mutect2, varscan2
- PAPPA2 | c.1248G>T p.G416= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as COSV100866728, COSV62775581; called by muse, mutect2
- PC | c.1716C>T p.D572= | Silent (SNP) | VAF 33/205 reads (16%) | catalogued as rs577570512, COSV58921072; called by muse, mutect2, varscan2
- PCDH12 | c.837G>A p.V279= | Silent (SNP) | VAF 52/185 reads (28%) | catalogued as COSV51520399; called by muse, mutect2, varscan2
- PCDHB3 | c.1191A>G p.V397= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as COSV50567119; called by muse, mutect2, varscan2
- PDHA2 | c.489C>T p.G163= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as COSV54778105; called by muse, mutect2, varscan2
- PLCE1 | c.5493G>A p.E1831= | Silent (SNP) | VAF 66/167 reads (40%) | catalogued as COSV53343590; called by muse, mutect2, varscan2
- PMFBP1 | c.591C>T p.C197= | Silent (SNP) | VAF 39/202 reads (19%) | catalogued as COSV52822160; called by muse, mutect2, varscan2
- POTEF | c.288C>T p.N96= | Silent (SNP) | VAF 62/356 reads (17%) | catalogued as COSV62540544, COSV62543242; called by muse, mutect2, varscan2
- PPP2CA | c.159T>C p.T53= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99196050; called by muse, mutect2, varscan2
- PTCHD4 | c.1923C>A p.I641= | Silent (SNP) | VAF 61/206 reads (30%) | catalogued as COSV59778738, COSV59780961; called by muse, mutect2, varscan2
- REG1A | c.276C>A p.G92= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as COSV52069188; called by muse, mutect2, varscan2
- RMND5A | c.684A>G p.Q228= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as COSV52153236; called by muse, mutect2, varscan2
- SCUBE3 | c.460C>A p.R154= | Silent (SNP) | VAF 13/101 reads (13%) | catalogued as rs1249043061, COSV51455757, COSV99234911; called by muse, mutect2, varscan2
- SEC23B | c.2178A>C p.P726= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV52719349, COSV52724634; called by muse, mutect2, varscan2
- SH3TC2 | c.3378C>A p.L1126= | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV60462112; called by muse, mutect2, varscan2
- SLC38A1 | c.1182C>G p.T394= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV67063175; called by muse, mutect2, varscan2
- SLC4A9 | c.2811G>A p.L937= (on ENST00000507527 / NM_001258428.2; = p.L913= on NM_031467.3) | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as rs1319555533, COSV99140138; called by muse, mutect2, varscan2
- SLC5A5 | c.513C>T p.T171= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs1419651478, COSV55832070, COSV99715221; called by muse, mutect2, varscan2
- SPAG4 | c.804C>A p.I268= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV65330245; called by muse, mutect2, varscan2
- SPRY3 | c.351T>A p.P117= | Silent (SNP) | VAF 56/154 reads (36%) | catalogued as COSV57142288; called by muse, mutect2, varscan2
- SPTA1 | c.1080C>A p.T360= | Silent (SNP) | VAF 150/245 reads (61%) | catalogued as COSV63750957; called by muse, mutect2, varscan2
- SPTBN4 | c.7476G>A p.K2492= | Silent (SNP) | VAF 24/156 reads (15%) | catalogued as COSV52538760; called by muse, mutect2, varscan2
- TBX18 | c.918C>A p.V306= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100858457, COSV63736423; called by muse, mutect2, varscan2
- TENM2 | c.3018C>A p.T1006= (on ENST00000518659 / NM_001122679.2; = p.T774= on NM_001080428.3) | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV69126765; called by muse, mutect2, varscan2
- TMLHE | c.873C>A p.L291= | Silent (SNP) | VAF 102/260 reads (39%) | catalogued as COSV57686257, COSV57686796; called by muse, mutect2, varscan2
- TRAJ10 | c.64A>T p.*22= | Silent (SNP) | VAF 18/112 reads (16%) | called by muse, mutect2, varscan2
- TRPC7 | c.1959C>T p.Y653= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs775960274, COSV61455704; called by mutect2, varscan2
- USH2A | c.2667G>A p.L889= | Silent (SNP) | VAF 43/222 reads (19%) | catalogued as COSV56348251, COSV56382247; called by muse, mutect2, varscan2
- USP51 | c.123G>T p.A41= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV72351545; called by muse, mutect2, varscan2
- VSIG4 | c.1092A>G p.G364= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV66073464; called by muse, mutect2, varscan2
- WDR7 | c.1029G>C p.L343= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV54350565; called by muse, mutect2, varscan2
- ZC3H18 | c.543G>A p.E181= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56323741; called by muse, mutect2, varscan2
- ZNF229 | c.2208C>T p.G736= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs777593082, COSV52160763; called by muse, mutect2, varscan2
- ZNF423 | c.2745G>T p.R915= (on ENST00000563137 / NM_001379286.1; = p.R907= on NM_015069.4) | Silent (SNP) | VAF 16/129 reads (12%) | catalogued as COSV52182816; called by muse, mutect2, varscan2
- ZNF605 | c.522T>C p.C174= | Silent (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- ZNF687 | c.2271C>T p.H757= | Silent (SNP) | VAF 42/257 reads (16%) | catalogued as rs760512566, COSV55016207; called by muse, mutect2, varscan2
- DAPK3 | c.630-263A>G | Intron (SNP) | VAF 6/43 reads (14%) | catalogued as COSV56662580; called by muse, mutect2, varscan2
- DIP2A | c.2394+28G>C | Intron (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- DIP2A | c.2394+29G>T | Intron (SNP) | VAF 10/98 reads (10%) | called by muse, mutect2
- MASP1 | c.1303+5286T>A | Intron (SNP) | VAF 20/148 reads (14%) | catalogued as COSV99962977; called by muse, mutect2, varscan2
- MIR1324 | n.62C>T | RNA (SNP) | VAF 6/54 reads (11%) | catalogued as rs79101433; called by mutect2, varscan2
- OR3A4P | n.973C>A | RNA (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- RPL10 | c.*2G>T | 3'UTR (SNP) | VAF 16/60 reads (27%) | catalogued as COSV99186409; called by muse, varscan2
- WDR44 | c.112-920C>A | Intron (SNP) | VAF 3/22 reads (14%) | catalogued as COSV54161879; called by muse, mutect2
